MMRF case MMRF_1805 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/984da3eb-5dde-4a77-a143-3edb86a288c7

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 48.6 years (17,741 days); ISS stage: II; Days to last known disease status: 1,023 days (2.8 years); Days to last follow up: 1,023 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 168 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 190 days; Days to treatment end: 259 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 190 days; Days to treatment end: 224 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 259 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 281 days; Days to treatment end: 313 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 314 days; Days to treatment end: 314 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 315 days; Days to treatment end: 315 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 415 days (1.1 years); Days to treatment end: 467 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 467 days (1.3 years); Days to treatment end: 498 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 532 days (1.5 years); Days to treatment end: 589 days (1.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 701 days (1.9 years); Days to treatment end: 889 days (2.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 889 days (2.4 years); Days to treatment end: 973 days (2.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 973 days (2.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -52 (ECOG 4): M Protein 1.73 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.34 mg/dL; Immunoglobulin G 28.5 g/L; Immunoglobulin A 3.28 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 0.9 µg/mL; Lactate Dehydrogenase 10.9 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 6.77 ×10⁹/L; Platelets 531 ×10⁹/L; Creatinine 33 µmol/L; Calcium 2.14 mmol/L; Albumin 24 g/L; Total Protein 7.7 g/dL; Glucose 5.8 mmol/L; C-Reactive Protein 17.8 mg/dL.
- Day 85 (ECOG 4): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 21.7 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 4.27 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 354 ×10⁹/L; Creatinine 53 µmol/L; Calcium 2.54 mmol/L; Albumin 36 g/L; Total Protein 7.8 g/dL; Glucose 4.9 mmol/L.
- Day 141 (ECOG 4): Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 19.2 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 45 µmol/L; Calcium 2.5 mmol/L; Albumin 39 g/L; Total Protein 8.2 g/dL; Glucose 4 mmol/L.
- Day 225 (ECOG 4): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 19 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 50 µmol/L; Calcium 2.42 mmol/L; Albumin 39 g/L; Total Protein 7.9 g/dL; Glucose 5.5 mmol/L.
- Day 302 (ECOG 4): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 51 µmol/L; Calcium 2.49 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 8.6 mmol/L.
- Day 407 (ECOG 4): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 54 µmol/L; Calcium 2.46 mmol/L; Albumin 37 g/L; Total Protein 7.7 g/dL; Glucose 4.5 mmol/L.
- Day 532 (ECOG 4): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 19.5 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 44 µmol/L; Calcium 2.5 mmol/L; Albumin 38 g/L; Total Protein 7.8 g/dL; Glucose 7.1 mmol/L.
- Day 602: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 22.3 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 58 µmol/L; Calcium 2.52 mmol/L; Albumin 41 g/L; Total Protein 8.3 g/dL; Glucose 5.7 mmol/L.
- Day 701 (ECOG 4): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 21 g/L; Immunoglobulin A 2.35 g/L; Immunoglobulin M 0.52 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 59 µmol/L; Calcium 2.55 mmol/L; Albumin 40 g/L; Total Protein 8.3 g/dL; Glucose 5.7 mmol/L.
- Day 792: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 1.42 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 58 µmol/L; Calcium 2.54 mmol/L; Albumin 40 g/L; Total Protein 8.3 g/dL; Glucose 5.5 mmol/L.
- Day 889: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 22.7 g/L; Immunoglobulin A 2.23 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 58 µmol/L; Calcium 2.57 mmol/L; Albumin 42 g/L; Total Protein 8.3 g/dL; Glucose 4.6 mmol/L.
- Day 973: Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 59 µmol/L; Calcium 2.61 mmol/L; Albumin 41 g/L; Total Protein 8.7 g/dL; Glucose 4.6 mmol/L.
- Day 1,023: Serum Free Immunoglobulin Light Chain, Kappa 2.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 60 µmol/L; Calcium 2.56 mmol/L; Albumin 40 g/L; Total Protein 8.5 g/dL; Glucose 7.1 mmol/L.

Other clinical attributes
- Day -52: Weight: 65 kg; Height: 163 cm.

Biospecimens (2 samples)
- Sample MMRF_1805_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -52 days.
- Sample MMRF_1805_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -52 days.
